Gene-level copy-number profile of tumor specimen TCGA-EJ-5507-01A from TCGA case TCGA-EJ-5507, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.1 years (19,759 days).
Specimen TCGA-EJ-5507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.9de01a3d-44d6-4ea5-aecf-4273d7691d21.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-5507-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a924792-a560-432f-a91f-c38570478190

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 11,018; copy number 2: 46,930; copy number 3: 1,761; copy number 4: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-5507-01A-01D-1574-01): tumor purity 0.68, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–1): PTEN.
- chr10:87,945,502–88,584,530, 5 genes (within-gene range 0–1): RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr21:10,328,411–15,627,342, 79 genes (within-gene range 0–2) (broad region; genes not listed).
- chr21:18,269,116–18,486,599, 2 genes (within-gene range 0–1): TMPRSS15, AL109763.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,631. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
